Surgical pathology report (de-identified scan), TCGA case TCGA-FG-7634, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western, specimen TCGA-FG-7634-01A (Primary Tumor).

Intraoperative Consultation:

A: Microscopic: Glioma.

Addendum

Addendum Diagnosis

Fluorescence in situ hybridization, performed at [REDACTED], demonstrates loss of both chromosomes 1p and 19q. A copy of this report is on file in the Department of Pathology.

Electronically Signed Out By

Clinical History:

l frontal neoplasm

Specimens Submitted As:

A:LEFT FRONTAL NEOPLASM

Gross Description:

Received fresh for intraoperative consultation, labelled with the patient's name and hospital number, and "left frontal neoplasm", are multiple, pink-tan, soft tissue fragments, 1 x 0.4 x 0.2 cm in aggregate. Representative sections are submitted for frozen section and touch imprint. The remainder of tissue is submitted entirely for permanents.

Summary of Cassettes:

A 1FS
2 permanents

Source: NCI Genomic Data Commons file 854f0f5b-2d85-453d-b40b-c55fbb6917e4 (TCGA-FG-7634.B6184DED-A667-44EA-A0D3-32EC6DF38516.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).